CCG case CUPP-B7TP — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f85efaeb-e8cb-4e58-8167-b6337e4c16b8

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Vital status: Dead; Days to death: 244 days; Year of death: 2002; Cause of death: Not Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 2001; Prior malignancy: no.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: First-Line Therapy.

Follow-up (1 entry)
- Days to follow up: 244 days; Year of follow up: 2002.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7TP-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7TP-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 25; Percent necrosis: 15; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 7.
